Somatic mutation profile of tumor specimen MP2PRT-PAPZPZ-TMP1-A (aliquot MP2PRT-PAPZPZ-TMP1-A-1-0-D-A83N-36) from MP2PRT case MP2PRT-PAPZPZ, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.4 years (1,232 days).
Specimen MP2PRT-PAPZPZ-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b7bd4d20-8e97-44d1-adfd-29f98604bbb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPZPZ-NM1-A (Blood Derived Cancer - Bone Marrow, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPZPZ-NM1-A-1-0-D-A83N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/212d430f-29e9-4feb-8361-ad1533745451

The open-access MAF lists 17 somatic variants for this specimen: 11 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Nonsense Mutation 1, Frame Shift Ins 1, 3'Flank 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.4427C>T p.P1476L | Missense Mutation (SNP) | VAF 37/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52113088, COSV52117573; called by muse, mutect2, varscan2
- CREBBP | c.4426C>T p.P1476S | Missense Mutation (SNP) | VAF 38/340 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CD084712; called by muse, mutect2, varscan2
- FRAS1 | c.3772G>A p.D1258N | Missense Mutation (SNP) | VAF 29/371 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs191708904; called by muse, mutect2
- NFS1 | c.1235G>A p.R412H | Missense Mutation (SNP) | VAF 64/265 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.175); catalogued as rs149205059; called by muse, mutect2, varscan2
- RP1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 22/672 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.072); catalogued as COSV55121175; called by muse, mutect2
- SMARCA5 | c.430C>T p.R144C | Missense Mutation (SNP) | VAF 76/349 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs751142387, COSV51647785, COSV99303436; called by muse, mutect2, varscan2
- ADAMTSL3 | c.3742A>G p.I1248V | Missense Mutation (SNP) | VAF 62/185 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRB3 | c.3181A>T p.R1061* | Nonsense Mutation (SNP) | VAF 56/255 reads (22%) | called by muse, mutect2, varscan2
- CADM1 | c.537G>T p.W179C | Missense Mutation (SNP) | VAF 92/306 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAM126A | c.971_973delinsACGCGGTTGGA p.G324Dfs*15 | Frame Shift Ins (INS) | VAF 60/225 reads (27%) | called by pindel, varscan2*
- SMG1 | c.7387T>C p.F2463L | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ADGRF4 | c.903C>T p.I301= | Silent (SNP) | VAF 94/329 reads (29%) | catalogued as rs768897472; called by muse, mutect2, varscan2
- ADGRF4 | c.904C>T p.L302= | Silent (SNP) | VAF 95/330 reads (29%) | called by muse, mutect2, varscan2
- FOXA1 | c.435G>A p.P145= | Silent (SNP) | VAF 50/972 reads (5%) | catalogued as rs1426984314; called by muse, mutect2
- SLC25A31 | c.48C>T p.D16= | Silent (SNP) | VAF 94/372 reads (25%) | catalogued as rs761883245, COSV55418278; called by muse, mutect2, varscan2
- AC233702.8 | chr17:21551315 C>T | 5'Flank (SNP) | VAF 23/629 reads (4%) | catalogued as COSV101194803; called by muse, mutect2
- IGHV2-70 | chr14:106770576 ins GGTTCCT | 3'Flank (INS) | VAF 34/156 reads (22%) | called by mutect2, pindel, varscan2
